FM case AD13542 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/2b66c0c3-ce76-49c5-902d-d0fb63f18c50

Male, 83.1 years: Carcinoma, NOS (ICD-O-3 8010/3) of the esophagus; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
